Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NQ-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old male recently diagnosed with poorly differentiated squamous cell carcinoma of mid-esophagus. Transhiatal esophagectomy/Tumor esophagus 4 x 4 cm tumor 7cm above GE junction.

PROCEDURE:

VERIFIED BY:

1. "Esophagus". 9.5 x 3.5 cm previously opened specimen of distal mid and distal esophagus and proximal stomach with 12 x 5 x 2 cm fragment of the periesophageal and perigastric fat. Specimen includes 7 cm of the distal esophagus and approximately 3.5 cm of the proximal stomach. 2.5 x 1.5 cm ulcer situated 2.5 cm distal to the proximal resection edge. The mucosa proximal and the distal from this lesion is wrinkled, gray and glistening. The gastric folds are pink-tan and unremarkable. The serial section through the lesion which occupies approximately 50% of the esophagea circumference reveal maximum depths of invasion 1.2 cm through the lamina propria inked of the _____. It approaches deep resection margin within less than 0.1 cm.
- 1A. Distal gastric margin. (Shaved).
- 1B-E. Consecutive sections of the longitudinal stirp of the mucosa from cephelea to caudal, distal margin inked green.
- 1F. Deepest tumor extension.
- 1G. Additional tumor section.
- 1H. Additional tumor section. Multiple possible lymph nodes identified in the areas of esophageal and perigastric fat submitted in cassette 11.
2. "Cervical esophageal margin". 2.5 cm segment of the tubal esophagus stapled at one end with great wrinkled, unremarkable mucosa. Sectioned. Submitted.
- 2A.
3. "Gastro hepatic ligament" 2 x 1 x 0.5 cm fragment of brown-tan adipose. Entirely submitted.
4. "Left jugular lymph node". 1 x 0.4 x 0.4 cm lymph node. Entirely submitted in cassette 4.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Squamous cell carcinoma

Depth of invasion: Muscularis propria

ICD O-3
Carcinoma, squamous cell NOS
8670/3
Site Esophagus, middle third
C15.4
JAN 17/14

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Number of positive lymph nodes: 0/3

Extranodal metastasis: Unknown

Pattern of invasion: Infiltrative

Esophageal and gastric resection margins involved: No

Deep resection margin involved: No

TNM classification: T2 N0 M0

PROCEDURE:

VERIFIED BY:

1. Esophagus, esophagectomy: Invasive squamous cell carcinoma, poorly-differentiated, at least 2.5 cm, invading into the muscularis propria. Margins of resection negative. Three periesophageal nodes negative for carcinoma. See template.

2. Cervicoesophageal margin, resection: Negative for carcinoma.

3. Gastrohepatic ligament, biopsy: Unremarkable adipose tissue.

4. Left jugular lymph node, resection: One lymph node negative for carcinoma.

, M.D.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file 59f277cd-6e2c-4779-8709-a5cc48e20510 (TCGA-L5-A8NQ.26722297-F12C-41B3-94E6-5686A6B7DEBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).